Somatic mutation profile of tumor specimen TCGA-E1-5304-01A (aliquot TCGA-E1-5304-01A-01D-1468-08) from TCGA case TCGA-E1-5304, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 42.4 years (15,481 days).
Specimen TCGA-E1-5304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21947ce8-a9ab-451a-aa66-4b88747fa285.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5304-10A (Blood Derived Normal), aliquot TCGA-E1-5304-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfc1dcd1-ef17-4d72-ae6b-289ee164c5c5

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 119/212 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 46/46 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- AHNAK | c.13891G>T p.D4631Y | Missense Mutation (SNP) | VAF 104/460 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV57208271; called by muse, mutect2, varscan2
- AKNA | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV56311878; called by muse, mutect2, varscan2
- ALKBH6 | c.336+1G>A p.X112_splice (on ENST00000252984 / NM_001297701.2; = p.X140_splice on NM_032878.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 37/137 reads (27%) | catalogued as COSV53324275; called by muse, mutect2, varscan2
- ALMS1 | c.9082T>G p.C3028G | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52506297; called by muse, mutect2, varscan2
- ATRX | c.6331C>T p.R2111* | Nonsense Mutation (SNP) | VAF 70/71 reads (99%) | catalogued as COSV64871723; called by muse, mutect2, varscan2
- C10orf53 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65107543; called by muse, mutect2
- CNGA1 | c.1504A>T p.I502F | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62053601; called by muse, mutect2
- COL25A1 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67648131; called by muse, mutect2, varscan2
- CSMD3 | c.1238A>G p.D413G | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV52136017; called by muse, mutect2, varscan2
- EPHA3 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as COSV60699046; called by muse, mutect2, varscan2
- ETAA1 | c.2033A>G p.N678S | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV55472486; called by muse, mutect2
- GBP3 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52517860; called by muse, mutect2, varscan2
- KCNJ13 | c.844T>C p.C282R | Missense Mutation (SNP) | VAF 146/279 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52084923; called by muse, mutect2, varscan2
- LGI1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 122/206 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs201376381, COSV65057719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP19 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs138516871; called by muse, mutect2, varscan2
- NAT8 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV55542360; called by muse, mutect2, varscan2
- PAX6 | c.775T>C p.S259P | Missense Mutation (SNP) | VAF 81/88 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53792491; called by muse, mutect2, varscan2
- PHF3 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV50315279; called by muse, mutect2, varscan2
- PKHD1 | c.11285C>A p.P3762Q | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64384476; called by muse, mutect2, varscan2
- RINT1 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 104/480 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV57557894; called by muse, mutect2, varscan2
- RPS6KA1 | c.1763G>T p.R588L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1427911631, COSV65175744, COSV65176735; called by muse, mutect2, varscan2
- STK3 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV69222582; called by muse, mutect2, varscan2
- DYNLL1 | c.165_166dup p.C56Ffs*12 | Frame Shift Ins (INS) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- ABCB10 | c.669G>C p.L223= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV100748003, COSV60620387; called by muse, mutect2, varscan2
- CCDC191 | c.279G>A p.E93= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as rs768191743, COSV55671096; called by muse, mutect2, varscan2
- EIF2AK4 | c.996G>A p.K332= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as rs1566988301, COSV55464364; called by muse, mutect2, varscan2
- FYCO1 | c.498G>A p.S166= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs149291592; called by muse, mutect2, varscan2
- PCSK5 | c.4896G>A p.A1632= | Silent (SNP) | VAF 140/278 reads (50%) | catalogued as rs373655020; called by muse, mutect2, varscan2
- RASEF | c.306C>T p.S102= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs779409903, COSV100525567; called by muse, varscan2
- OSGIN1 | n.966C>T | RNA (SNP) | VAF 23/136 reads (17%) | catalogued as rs541053223, COSV59674868; called by muse, mutect2, varscan2
